Somatic mutation profile of tumor specimen MP2PRT-PAVDWB-TMP1-B (aliquot MP2PRT-PAVDWB-TMP1-B-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAVDWB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.8 years (2,479 days).
Specimen MP2PRT-PAVDWB-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c69ed892-c566-498c-a173-5b7f61dc1159.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVDWB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVDWB-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29aec372-8eb3-4d79-9d98-6c55004be1fb

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, RNA 1, Nonsense Mutation 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 46/269 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 53/270 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- DGKI | c.553G>A p.V185I | Missense Mutation (SNP) | VAF 54/292 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as rs779164061, COSV55950318; called by muse, mutect2, varscan2
- FGD5 | c.2284C>T p.R762W | Missense Mutation (SNP) | VAF 160/344 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768184216; called by muse, mutect2, varscan2
- PSD2 | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 74/408 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs753531914, COSV51207904, COSV51212681; called by muse, varscan2
- TMC2 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 79/487 reads (16%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs1172017274; called by muse, mutect2, varscan2
- UTF1 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 267/918 reads (29%) | catalogued as rs774588450; called by muse, mutect2, varscan2
- ZBTB7C | c.151G>A p.V51I | Missense Mutation (SNP) | VAF 152/494 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs549573381, COSV59688144; called by muse, mutect2, varscan2
- CACNA1G | c.6269G>A p.S2090N | Missense Mutation (SNP) | VAF 122/414 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, varscan2
- GAL3ST1 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 152/384 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, varscan2
- GPR174 | c.229T>G p.F77V | Missense Mutation (SNP) | VAF 79/787 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ZNF341 | c.10delinsTT p.A4Ffs*4 | Frame Shift Ins (INS) | VAF 178/639 reads (28%) | called by pindel, varscan2*
- MCOLN1 | c.1536C>T p.L512= | Silent (SNP) | VAF 130/310 reads (42%) | called by muse, varscan2
- MROH5 | c.228G>A p.E76= | Silent (SNP) | VAF 53/387 reads (14%) | catalogued as rs1184457735; called by muse, mutect2, varscan2
- TTC6 | c.576T>A p.A192= | Silent (SNP) | VAF 198/730 reads (27%) | called by muse, mutect2, varscan2
- DMKN | c.1039-188G>A | Intron (SNP) | VAF 113/269 reads (42%) | catalogued as rs779452708; called by muse, mutect2, varscan2
- REXO1L1P | n.1553G>A | RNA (SNP) | VAF 61/843 reads (7%) | catalogued as rs146084583; called by muse, mutect2, varscan2
